TCGA case TCGA-57-1586 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/48e66676-dbed-48a4-9a7f-a6d247b15c17

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 66.5 years (24,304 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 679 days (1.9 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 11-20 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 49 days; Days to treatment end: 163 days; Number of cycles: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Gemcitabine Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 259 days; Number of cycles: 4.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 323 days; Days to treatment end: 406 days (1.1 years); Number of cycles: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 433 days (1.2 years); Days to treatment end: 542 days (1.5 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 553 days (1.5 years); Number of cycles: 1.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 67.2 years (24,563 days); Days to diagnosis: 259 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 259 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 259 days; Evidence of recurrence type: Positive Biomarker(s).
- Days to follow up: 679 days (1.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-57-1586-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-57-1586-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-57-1586-01A-01-BS1: Section location: Top; Percent tumor cells: 94; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
- Sample TCGA-57-1586-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-57-1586-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1; Shortest dimension: 0.7.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 2: Pharmaceutical therapy drug name: Gemzar; Therapy regimen: Progression.
- Drug treatment 4: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 679 days; disease-specific survival: no event (censored), 679 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 259 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-57-1586-01A-02D-0559-01): tumor purity 0.84, ploidy 2.59, whole-genome doublings 1.
